Somatic mutation profile of tumor specimen TCGA-MH-A55W-01A (aliquot TCGA-MH-A55W-01A-11D-A26P-10) from TCGA case TCGA-MH-A55W, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 50.9 years (18,573 days).
Specimen TCGA-MH-A55W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68e1d268-e2cc-4fa7-b5bd-f2b6f7b5a054.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MH-A55W-10A (Blood Derived Normal), aliquot TCGA-MH-A55W-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fee5b8e5-5a78-4733-8d35-f5e7ebcdfba7

The open-access MAF lists 101 somatic variants for this specimen: 78 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 18, Frame Shift Del 11, Splice Region 5, Nonsense Mutation 4, Splice Site 4, Intron 3, 5'UTR 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.4521T>A p.S1507R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV61363803; called by mutect2, varscan2
- ACKR4 | c.32A>C p.Y11S | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV51442820; called by muse, mutect2, varscan2
- ACTR10 | c.500G>C p.G167A | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.119); catalogued as COSV54299088; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2615G>T p.S872I | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55002555; called by muse, mutect2, varscan2
- ADCY3 | c.2175C>T p.L725= | Splice Region (SNP) | VAF 74/132 reads (56%) | catalogued as COSV53169421; called by muse, varscan2
- ADCY3 | c.2174T>G p.L725R | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53169431; called by muse, varscan2
- ADNP | c.1979T>C p.L660P | Missense Mutation (SNP) | VAF 96/214 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV62426032; called by muse, mutect2, varscan2
- ANK1 | c.659A>C p.N220T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV55886236; called by muse, varscan2
- ARHGEF15 | c.433T>G p.S145A | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.952); catalogued as COSV62725699; called by muse, mutect2, varscan2
- BBS9 | c.1249G>C p.V417L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as COSV54175342; called by muse, mutect2, varscan2
- CCDC15 | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV61083072; called by muse, mutect2, varscan2
- CELSR2 | c.5368G>A p.G1790S | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54775239; called by muse, mutect2, varscan2
- CFAP44 | c.1172T>G p.I391R | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV55613179; called by muse, mutect2
- CIDEB | c.329C>G p.P110R | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV51866654; called by muse, mutect2, varscan2
- CIP2A | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375108755; called by muse, varscan2
- CLASP1 | c.2705C>G p.T902S | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV55329290; called by muse, mutect2, varscan2
- CSNK1E | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs770285198, COSV63291514; called by muse, mutect2, varscan2
- CYP2C8 | c.801C>G p.F267L | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.603); catalogued as COSV64876413, COSV64877881; called by muse, mutect2
- DAPK2 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs1314460243, COSV56046544; called by mutect2, varscan2
- DLGAP1 | c.2498C>T p.T833I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs538990113, COSV59816440; called by muse, mutect2, varscan2
- DPF2 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52890222; called by muse, mutect2, varscan2
- DSG4 | c.95T>A p.F32Y | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57393758; called by muse, varscan2
- ELL3 | c.1005T>G p.I335M | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.15); catalogued as COSV55857195; called by muse, mutect2, varscan2
- FAT3 | c.11713T>A p.L3905M | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.249); catalogued as COSV53136310; called by muse, mutect2, varscan2
- FBXO47 | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100960606, COSV65242140; called by muse, mutect2, varscan2
- FYCO1 | c.969G>T p.E323D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.362); catalogued as COSV56117292; called by muse, mutect2, varscan2
- GEN1 | c.2056C>G p.Q686E | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV58057377; called by muse, mutect2
- GOLGA2 | c.1980G>A p.Q660= | Splice Region (SNP) | VAF 18/50 reads (36%) | catalogued as COSV57853282; called by muse, mutect2, varscan2
- GRSF1 | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV54656057; called by muse, mutect2, varscan2
- HLCS | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs148324626; called by muse, mutect2, varscan2
- IFT122 | c.2196del p.F732Lfs*19 (on ENST00000348417 / NM_052989.3; = p.F673Lfs*19 on NM_018262.4) | Frame Shift Del (DEL) | VAF 88/262 reads (34%) | catalogued as COSV99959119; called by pindel, varscan2
- ITSN2 | c.3384T>C p.P1128= | Splice Region (SNP) | VAF 33/66 reads (50%) | catalogued as COSV61950028; called by muse, mutect2, varscan2
- KIF1A | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100242099, COSV57493914; called by muse, mutect2
- KNG1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53979100; called by muse, mutect2, varscan2
- LAMTOR2 | c.254del p.R85Qfs*63 | Frame Shift Del (DEL) | VAF 98/313 reads (31%) | catalogued as COSV63108892; called by mutect2, pindel, varscan2
- LIPI | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 41/139 reads (29%) | catalogued as COSV60713318; called by muse, mutect2, varscan2
- MDN1 | c.3583C>T p.Q1195* | Nonsense Mutation (SNP) | VAF 63/125 reads (50%) | catalogued as COSV65524470; called by muse, mutect2, varscan2
- MMP17 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1255143525, COSV62178393; called by muse, mutect2, varscan2
- MTERF2 | c.1125T>G p.F375L | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV53527916; called by muse, mutect2, varscan2
- NCOA3 | c.357G>A p.Q119= | Splice Region (SNP) | VAF 13/38 reads (34%) | catalogued as COSV59070423; called by muse, mutect2, varscan2
- NIPSNAP2 | c.233-1G>C p.X78_splice | Splice Site (SNP) | VAF 81/197 reads (41%) | catalogued as COSV59051725; called by muse, mutect2, varscan2
- NPHP1 | c.834T>A p.N278K | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57209783; called by muse, mutect2, varscan2
- NRBP1 | c.854A>T p.Q285L | Missense Mutation (SNP) | VAF 204/362 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV51994949; called by muse, varscan2
- NRG3 | c.712T>C p.S238P | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV64570960; called by muse, mutect2, varscan2
- OR13G1 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs200763482, COSV100687494, COSV62943805; called by muse, mutect2
- PCDH15 | c.3850G>T p.V1284F | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57342992; called by muse, mutect2, varscan2
- PKHD1 | c.6991A>C p.I2331L | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV61884045; called by muse, mutect2, varscan2
- PNCK | c.68+1G>C p.X23_splice (on ENST00000340888 / NM_001366975.1; = p.X106_splice on NM_001039582.3) | Splice Site (SNP) | VAF 71/84 reads (85%) | catalogued as COSV61744424; called by muse, mutect2, varscan2
- RALBP1 | c.1166C>G p.P389R | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV50036478; called by muse, mutect2, varscan2
- RBBP6 | c.3068A>T p.N1023I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV60506463; called by muse, mutect2, varscan2
- RBM5 | c.2373T>A p.Y791* | Nonsense Mutation (SNP) | VAF 56/134 reads (42%) | catalogued as COSV61738160; called by muse, varscan2
- RDH13 | c.82G>T p.G28W | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52561638; called by muse, mutect2, varscan2
- RFX8 | c.1517C>A p.P506H (on ENST00000646446; = p.P435H on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65179997; called by muse, mutect2, varscan2
- SCAF11 | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs755024747, COSV56978123; called by muse, mutect2, varscan2
- SHANK3 | c.4018C>G p.P1340A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV53188138; called by muse, mutect2, varscan2
- SORBS1 | c.3389A>C p.K1130T | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as COSV53360352; called by muse, mutect2, varscan2
- SPTLC2 | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV53641245; called by muse, mutect2, varscan2
- STK24 | c.468C>A p.D156E | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64823235; called by muse, mutect2, varscan2
- STK40 | c.467T>A p.L156H | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63735876; called by muse, mutect2, varscan2
- STT3A | c.883T>G p.F295V | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV67065070; called by muse, mutect2, varscan2
- SUCLA2 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.124); catalogued as COSV66222466; called by muse, mutect2, varscan2
- TNXB | c.5768G>A p.R1923H (on ENST00000647633; = p.R1676H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs755779024, COSV64482499; called by muse, mutect2, varscan2
- UBR4 | c.6026C>T p.P2009L | Missense Mutation (SNP) | VAF 145/384 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64393066; called by muse, mutect2, varscan2
- WWC3 | c.674A>C p.K225T | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as COSV66504693; called by muse, mutect2, varscan2
- ADGRA1 | c.175_176del p.F59Lfs*252 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- AKAP12 | c.2134del p.Q712Rfs*54 | Frame Shift Del (DEL) | VAF 42/140 reads (30%) | called by mutect2, pindel, varscan2
- C2CD2L | c.1619_1626+6del p.X540_splice | Splice Site (DEL) | VAF 38/127 reads (30%) | called by mutect2, pindel, varscan2
- CZIB | c.262-5del | Splice Region (DEL) | VAF 57/154 reads (37%) | called by mutect2, pindel, varscan2
- GCM1 | c.946_947insTTT p.N315_Y316insF | In Frame Ins (INS) | VAF 32/102 reads (31%) | called by mutect2, varscan2
- KCNK5 | c.754_761del p.V252Sfs*3 | Frame Shift Del (DEL) | VAF 27/96 reads (28%) | called by mutect2, pindel, varscan2
- MARK3 | c.2039del p.R680Pfs*46 (on ENST00000429436 / NM_001128918.3; = p.R656Pfs*46 on NM_002376.6) | Frame Shift Del (DEL) | VAF 59/200 reads (30%) | called by mutect2, pindel, varscan2
- NEB | c.1079_1085del p.D360Vfs*14 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel
- NSD1 | c.6009+5_6009+8del p.X2003_splice | Splice Site (DEL) | VAF 22/71 reads (31%) | called by pindel, varscan2
- RANBP2 | c.3185del p.N1062Tfs*6 | Frame Shift Del (DEL) | VAF 47/115 reads (41%) | called by mutect2, pindel, varscan2
- SLC32A1 | c.221_242del p.G74Efs*45 | Frame Shift Del (DEL) | VAF 55/118 reads (47%) | called by mutect2, varscan2
- TAF6 | c.110del p.Q37Rfs*3 | Frame Shift Del (DEL) | VAF 139/410 reads (34%) | called by mutect2, pindel, varscan2
- ZBTB2 | c.1525_1528del p.E509Pfs*4 | Frame Shift Del (DEL) | VAF 38/121 reads (31%) | called by mutect2, pindel, varscan2
- ZNF799 | c.1052C>A p.S351* | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | called by muse, varscan2
- ADGRV1 | c.5730T>C p.D1910= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as rs750636923, COSV67989214; called by mutect2, varscan2
- C9orf78 | c.387C>A p.I129= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV59615785; called by muse, mutect2, varscan2
- CD163L1 | c.3111C>A p.R1037= | Silent (SNP) | VAF 50/176 reads (28%) | catalogued as COSV58019276; called by muse, mutect2, varscan2
- COPZ2 | c.621G>C p.S207= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV50058024; called by muse, mutect2
- CPZ | c.795G>C p.L265= (on ENST00000360986 / NM_001014447.3; = p.L254= on NM_003652.3) | Silent (SNP) | VAF 63/183 reads (34%) | catalogued as COSV59924040; called by muse, mutect2, varscan2
- DGLUCY | c.1617C>T p.H539= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV56367701; called by muse, mutect2, varscan2
- DSG2 | c.1545T>C p.V515= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV55200454; called by muse, mutect2, varscan2
- EGFLAM | c.1599C>A p.G533= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV59308069; called by muse, mutect2, varscan2
- FAAP100 | c.351T>C p.P117= | Silent (SNP) | VAF 120/510 reads (24%) | catalogued as COSV59886306; called by muse, mutect2, varscan2
- IQSEC3 | c.2922G>A p.L974= (on ENST00000538872 / NM_001170738.2; = p.L671= on NM_015232.1) | Silent (SNP) | VAF 94/179 reads (53%) | catalogued as rs782359054, COSV58286942; called by muse, mutect2, varscan2
- KCNN3 | c.1356G>A p.K452= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as COSV55220475; called by muse, mutect2, varscan2
- MARK2 | c.1533C>G p.S511= (on ENST00000402010 / NM_001039469.2; = p.S477= on NM_017490.4) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV59285510, COSV59287145; called by muse, mutect2, varscan2
- MINDY2 | c.1446A>T p.V482= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV57507501; called by muse, mutect2, varscan2
- OR13G1 | c.162G>T p.T54= | Silent (SNP) | VAF 50/155 reads (32%) | catalogued as COSV62943288, COSV62943347; called by muse, mutect2
- TBC1D19 | c.4T>C p.L2= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV53518437; called by mutect2, varscan2
- TBC1D9 | c.546C>T p.S182= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs759134276, COSV71307871; called by muse, mutect2, varscan2
- TCHHL1 | c.471G>A p.V157= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as rs1172502692, COSV64286430; called by muse, mutect2, varscan2
- TSPEAR | c.678C>T p.T226= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs782276897, COSV59968935; called by muse, mutect2, varscan2
- ABHD11 | c.*1G>C | 3'UTR (SNP) | VAF 80/165 reads (48%) | catalogued as COSV99766850; called by muse, mutect2, varscan2
- DNAJC6 | c.22+44942C>T | Intron (SNP) | VAF 20/52 reads (38%) | catalogued as COSV54777676; called by muse, mutect2
- MCM5 | c.167+1062A>G | Intron (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- RPL24 | c.-23T>C | 5'UTR (SNP) | VAF 68/205 reads (33%) | catalogued as COSV101231186; called by muse, mutect2, varscan2
- SEC13 | c.165-744T>C | Intron (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
